Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A1YX, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A1YX-06A (Metastatic).

Prof.Dr...

1CB-0-3

Melanoma, NOS 8726/3

Site: Subcutaneous tissue, NOS C49.9

for 7/24/11

UUID:SEA2F816-4993-428A-8D97-97496ESF1368

Patient: Xxxx
geb. **.*.****

Datum:

Translation of pathology report F

Sample

Gross Pathology

Cryofixed specimen with a weight of

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 70 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine. Some apoptotic cells are present. There is a high nucleo/cytoplasmatic ratio. The mitotic count is 1 mitosis per square millimetre. The tumor cells have a middle sized cytoplasm. The tumor shows a nest like growth pattern with dyshaesive areals. Lymphocytic infiltrates compound approx. 10 percent of the tissue cells.

Diagnosis: Parts of a malignat tumor, consistent with a metastasis of a melanoma.

Dr.

Source: NCI Genomic Data Commons file adfcaf50-7a85-4edf-8cb8-5f1f5bac8f88 (TCGA-FS-A1YX.5EA2F816-4993-428A-8D97-97496E5F1360.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).